Somatic mutation profile of cancer-model specimen HCM-BROD-0418-C71-85B (3D Neurosphere, passage 6; aliquot HCM-BROD-0418-C71-85B-01D-A87L-36), derived from the primary tumor of HCMI case HCM-BROD-0418-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.5 years (16,625 days).
Specimen HCM-BROD-0418-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 990b336e-eadc-41d5-b4e7-44cd4b8b1d98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0418-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0418-C71-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96bdeaae-56ab-4077-adb3-a8e3e8eec111

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Intron 3, Nonsense Mutation 2, Translation Start Site 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as rs1338391423, CM992590; called by muse, mutect2, varscan2
- BRDT | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 162/342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475548899; called by muse, mutect2, varscan2
- CFAP57 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 168/293 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752549029, COSV100993943; called by muse, mutect2, varscan2
- CHD9 | c.6952C>T p.P2318S | Missense Mutation (SNP) | VAF 254/392 reads (65%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs771079651, COSV54616482; called by muse, mutect2
- DNAH2 | c.5437G>A p.V1813I | Missense Mutation (SNP) | VAF 271/546 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs754083186, COSV66728727; called by muse, varscan2
- DYSF | c.4072G>A p.V1358M | Missense Mutation (SNP) | VAF 254/514 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as rs760627822, COSV50553093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR149 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 54/604 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV67665904; called by muse, mutect2
- H1-1 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 224/455 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as COSV55119404; called by muse, mutect2, varscan2
- KCNH5 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 228/452 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs200292403; called by muse, mutect2, varscan2
- KRT84 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 225/441 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57771546; called by muse, mutect2, varscan2
- MROH2B | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 318/504 reads (63%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.477); catalogued as rs1461880389; called by muse, mutect2, varscan2
- MSTN | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 208/409 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1315783994, COSV53621476; called by muse, mutect2, varscan2
- MYH2 | c.3653G>A p.R1218Q | Missense Mutation (SNP) | VAF 270/538 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs139755852; called by muse, mutect2, varscan2
- MYO1B | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747519171; called by muse, mutect2, varscan2
- OR2T2 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 272/582 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs200389028, COSV100737564; called by muse, mutect2, varscan2
- PRKCB | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as rs1424365930; called by muse, mutect2, varscan2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 238/498 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- SLC26A6 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 195/379 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1479041553, COSV99375489; called by muse, mutect2, varscan2
- TMEM145 | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 201/383 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs775934464; called by muse, mutect2, varscan2
- TTC13 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/526 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs1451113980; called by muse, mutect2
- TTN | c.66602C>G p.S22201* (on ENST00000591111; = p.S14777* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 21/460 reads (5%) | catalogued as COSV59881954; called by muse, mutect2
- TTN | c.41332G>A p.A13778T (on ENST00000591111; = p.A6354T on NM_003319.4) | Missense Mutation (SNP) | VAF 137/319 reads (43%) | PolyPhen possibly damaging (0.725); catalogued as rs761783891; called by muse, mutect2, varscan2
- CLCN1 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 199/776 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4B | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 271/562 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX35 | c.153G>C p.R51S | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMD | c.6910A>T p.K2304* | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- DSP | c.7610G>T p.G2537V | Missense Mutation (SNP) | VAF 18/583 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENPEP | c.1417G>T p.V473F | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRRTM4 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 247/524 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRR23B | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 33/584 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2
- RALA | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 91/415 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA3E | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 187/689 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SULF2 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 153/308 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ZAN | c.6034A>G p.S2012G | Missense Mutation (SNP) | VAF 132/570 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5C | c.112_113del p.S38* | Frame Shift Del (DEL) | VAF 221/528 reads (42%) | called by mutect2, pindel, varscan2
- CYP46A1 | c.936G>A p.A312= | Silent (SNP) | VAF 201/443 reads (45%) | catalogued as rs1007746329; called by muse, mutect2, varscan2
- DAB2IP | c.525G>A p.T175= (on ENST00000408936; = p.T147= on NM_032552.3) | Silent (SNP) | VAF 212/494 reads (43%) | catalogued as rs559896738, COSV52257503; called by muse, mutect2, varscan2
- LRBA | c.7584G>A p.Q2528= | Silent (SNP) | VAF 21/368 reads (6%) | catalogued as rs1357782730; called by muse, mutect2
- MYOCD | c.543C>T p.D181= | Silent (SNP) | VAF 183/407 reads (45%) | catalogued as rs368720240, COSV58497356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN3 | c.1662C>T p.N554= | Silent (SNP) | VAF 163/312 reads (52%) | catalogued as rs919588386; called by muse, mutect2, varscan2
- RBSN | c.1311G>A p.L437= | Silent (SNP) | VAF 27/557 reads (5%) | catalogued as COSV53795612; called by muse, mutect2
- SNAP91 | c.180C>T p.A60= | Silent (SNP) | VAF 152/152 reads (100%) | catalogued as rs372957792; called by muse, mutect2, varscan2
- TLL1 | c.795A>G p.R265= | Silent (SNP) | VAF 11/207 reads (5%) | called by muse, mutect2
- TMEM132B | c.1047G>A p.S349= | Silent (SNP) | VAF 194/402 reads (48%) | catalogued as rs377055980; called by muse, mutect2, varscan2
- UGT3A1 | c.1363C>T p.L455= | Silent (SNP) | VAF 260/621 reads (42%) | called by muse, mutect2, varscan2
- WBP1 | c.600C>A p.P200= | Silent (SNP) | VAF 207/453 reads (46%) | called by muse, mutect2, varscan2
- C4orf50 | c.-819G>A | 5'UTR (SNP) | VAF 89/293 reads (30%) | catalogued as rs553787371; called by muse, mutect2, varscan2
- CD72 | c.262+58C>A | Intron (SNP) | VAF 306/306 reads (100%) | called by muse, mutect2, varscan2
- FBRSL1 | c.489+1294G>A | Intron (SNP) | VAF 360/735 reads (49%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+16745C>T | Intron (SNP) | VAF 33/326 reads (10%) | called by muse, mutect2, varscan2
